CPTAC case 03BR011 — Breast — Ductal and Lobular Neoplasms (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/4b355c1d-4202-4291-93ec-7882e702bd20

Demographics
Race: white.

Diagnoses (1)
1. Invasive lobular carcinoma: Tissue or organ of origin: Breast, NOS; Age at diagnosis: 71.0 years (25,945 days); AJCC pathologic stage: Stage IIIA.

Biospecimens (3 samples)
- Sample CPT008548: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Samples CPT008734, CPT008926 (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
